Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017981-03A.3 (aliquot TARGET-15-SJMPAL017981-03A.3-01D) from TARGET case TARGET-15-SJMPAL017981, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.5 years (184 days).
Specimen TARGET-15-SJMPAL017981-03A.3: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b96fcb82-4ba4-458c-92bc-66eec3e1795c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017981-10A (Blood Derived Normal), aliquot TARGET-15-SJMPAL017981-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/033498d7-d81d-4a8a-9faa-2025ad3ef4a2

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 18/155 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 44/158 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- DDX3X | c.1048C>T p.R350W (on ENST00000399959; = p.R351W on NM_001356.5) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67864267; called by muse, mutect2, varscan2
- FAM131A | c.384C>A p.S128R (on ENST00000310585; = p.S159R on NM_144635.5) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99658407; called by muse, mutect2
- FAM186A | c.4191G>C p.M1397I | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs546296194, COSV59245676, COSV59247060; called by muse, varscan2
- SLCO3A1 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as COSV59231265; called by muse, mutect2, varscan2
- BSN | c.2841C>A p.D947E | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- HECW2 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.416); called by muse, mutect2
- KLF11 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.462); called by muse, mutect2
- PHC2 | c.2401G>T p.E801* (on ENST00000257118 / NM_198040.2; = p.E266* on NM_004427.4) | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- TNRC18 | c.7747G>A p.G2583R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- AURKAIP1 | c.390G>T p.V130= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- TNFSF9 | c.351C>A p.G117= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
